Somatic mutation profile of tumor specimen TCGA-AA-3492-01A (aliquot TCGA-AA-3492-01A-01D-1408-10) from TCGA case TCGA-AA-3492, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AA-3492-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81aaeb94-6f09-442d-8c31-2d2924073e44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3492-11A (Solid Tissue Normal), aliquot TCGA-AA-3492-11A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d14f27c8-3c01-4cd1-9a5d-ba13ba5ab11c

The open-access MAF lists 2,476 somatic variants for this specimen: 1,861 protein-altering or splice-affecting, 563 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,343, Silent 563, Frame Shift Del 331, Frame Shift Ins 72, Nonsense Mutation 62, Intron 26, In Frame Del 18, Splice Site 16, Splice Region 14, RNA 11, 3'UTR 10, Translation Start Site 3.

Variants (750 of 2,476; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXIN2 | c.1994dup p.N666Qfs*41 | Frame Shift Ins (INS) | VAF 22/42 reads (52%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KMT2A | c.2318dup p.S774Vfs*12 | Frame Shift Ins (INS) | VAF 34/98 reads (35%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MKRN3 | c.482dup p.A162Gfs*15 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, varscan2
- MOCS2 | c.65dup p.L23Ifs*5 | Frame Shift Ins (INS) | VAF 18/38 reads (47%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, varscan2
- NPC1 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs753768576, CM015254, COSV52578701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 19/36 reads (53%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by pindel, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 38/87 reads (44%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- RPE65 | c.1067dup p.N356Kfs*9 | Frame Shift Ins (INS) | VAF 15/46 reads (33%) | catalogued as rs281865520; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- SHANK3 | c.3658del p.A1220Pfs*57 | Frame Shift Del (DEL) | VAF 9/11 reads (82%) | catalogued as rs762292772; ClinVar: pathogenic; called by mutect2, varscan2
- TGFBR1 | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064796037, COSV66625753; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TGFBR2 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893815, CM050762, CM159806, COSV55442586, COSV55450248; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.2546A>G p.D849G | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1038670077, COSV55296341; called by muse, mutect2, varscan2
- A2ML1 | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100229371, COSV55290598; called by muse, mutect2, varscan2
- A3GALT2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs760406069, COSV100378113; called by mutect2, varscan2
- AARD | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs1458736491, COSV65599835; called by muse, mutect2, varscan2
- AARS2 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs544333323, COSV55113682; called by muse, mutect2, varscan2
- ABCA13 | c.12695T>C p.L4232P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291129; called by muse, mutect2
- ABCA5 | c.4064G>T p.G1355V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303540015, COSV67016866; called by muse, mutect2, varscan2
- ABCA6 | c.2003T>C p.F668S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52638657; called by muse, mutect2, varscan2
- ABCA7 | c.3410C>T p.T1137I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1260834934, COSV54029417; called by muse, mutect2, varscan2
- ABCC2 | c.3922C>T p.R1308W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1024856612, COSV64987948; called by muse, mutect2, varscan2
- ABHD6 | c.445A>C p.M149L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99916832; called by muse, mutect2, varscan2
- ABL1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs372727500; called by muse, mutect2, varscan2
- AC004593.2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs375395261; called by muse, mutect2, varscan2
- AC004832.3 | c.867G>A p.W289* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV56741788, COSV56742506; called by muse, mutect2, varscan2
- AC104452.1 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.109); catalogued as COSV56469483; called by muse, mutect2, varscan2
- ACACB | c.4901T>A p.I1634N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58134526; called by muse, mutect2, varscan2
- ACAN | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767131816, COSV61360305; called by muse, mutect2, varscan2
- ACAP1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs746523412, COSV50135941; called by muse, mutect2, varscan2
- ACE | c.3212A>G p.Q1071R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.57); catalogued as COSV99326131; called by muse, mutect2, varscan2
- ACO2 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs755695367, COSV99346915; called by muse, mutect2, varscan2
- ACTC1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1437269590, COSV51757644, COSV99291859; called by muse, mutect2, varscan2
- ACTL10 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as COSV55776114; called by muse, mutect2, varscan2
- ACTL9 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.046); catalogued as rs930779979, COSV61005740; called by muse, mutect2, varscan2
- ACTN4 | c.2510G>A p.R837Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs368563044; called by muse, mutect2, varscan2
- ACTR1A | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1370250172, COSV99487661; called by muse, mutect2, varscan2
- ACVR1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV55119002; called by muse, mutect2, varscan2
- ACVR1B | c.85del p.V29Sfs*57 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs1425551425; called by mutect2, pindel, varscan2
- ACVR2B | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV61702255; called by muse, mutect2, varscan2
- ADAM19 | c.2464G>A p.G822R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs536485712, COSV57430009; called by muse, mutect2, varscan2
- ADAMTS12 | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs148278677, COSV100711781; called by muse, mutect2, varscan2
- ADAMTS15 | c.2442C>A p.D814E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54505415; called by muse, mutect2, varscan2
- ADAMTS6 | c.230A>T p.D77V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV66859701; called by muse, mutect2, varscan2
- ADAMTS9 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99898394; called by muse, mutect2, varscan2
- ADCK1 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV53080834; called by muse, mutect2, varscan2
- ADCY1 | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV52030315, COSV52036132, COSV99812390; called by muse, mutect2, varscan2
- ADCY1 | c.2789T>C p.V930A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV99811028; called by mutect2, varscan2
- ADCY6 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.229); catalogued as rs761126585, COSV57167886; called by muse, mutect2, varscan2
- ADGRB2 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV57073636; called by muse, mutect2, varscan2
- ADGRE5 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as rs568383810, COSV54410623; called by muse, mutect2, varscan2
- ADGRV1 | c.8056C>T p.P2686S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV67985125; called by muse, mutect2, varscan2
- ADGRV1 | c.18330T>A p.Y6110* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as rs1385277579, COSV67985128; called by muse, mutect2, varscan2
- ADPGK | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61173958; called by muse, mutect2, varscan2
- ADPRH | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751996500, COSV100813339, COSV63694849; called by muse, mutect2, varscan2
- ADRA2C | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57467256; called by muse, mutect2, varscan2
- AFDN | c.4474C>T p.R1492C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs748333996, COSV60044519; called by muse, mutect2, varscan2
- AGAP1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs773218170, COSV58319853, COSV58340917; called by muse, mutect2, varscan2
- AGAP1 | c.530del p.G177Efs*6 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | catalogued as COSV58333265; called by mutect2, pindel, varscan2
- AGRN | c.5926G>A p.G1976S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs781607506, COSV65069578; called by muse, mutect2, varscan2
- AHI1 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs772731992, COSV55627685; called by muse, mutect2, varscan2
- AIFM3 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV58999385; called by muse, mutect2, varscan2
- AKAP3 | c.2513G>T p.G838V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50539243; called by muse, mutect2, varscan2
- AKAP8 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV99511617; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKAP9 | c.10655T>C p.V3552A (on ENST00000359028; = p.V3528A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62346191; called by muse, mutect2, varscan2
- AKNAD1 | c.2039G>A p.C680Y | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.176); catalogued as COSV62196467, COSV62198398; called by muse, mutect2
- AKR1B15 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV71151134, COSV71151549, COSV71151818; called by muse, mutect2, varscan2
- AKT1 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs751243134, COSV62573384; called by muse, varscan2
- AL035460.1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.094); catalogued as rs1220594798, COSV100730070; called by muse, mutect2
- ALDH1A2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as COSV51081438; called by muse, mutect2, varscan2
- ALDH3B2 | c.1021T>G p.F341V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62428246; called by muse, mutect2, varscan2
- ALG3 | c.865T>A p.F289I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56611483; called by muse, varscan2
- ALMS1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52509796; called by muse, mutect2, varscan2
- ALMS1 | c.5554C>T p.P1852S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52509809, COSV52513583; called by muse, mutect2, varscan2
- ALMS1 | c.12037G>A p.G4013S | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs541576664, COSV52508643, COSV52509816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMACR | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as rs113840552, COSV100162751, COSV59462134; called by muse, mutect2, varscan2
- AMBRA1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as rs777571634, COSV54053870; called by muse, mutect2, varscan2
- AMER1 | c.1633T>C p.F545L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV57659449, COSV57660804; called by muse, mutect2, varscan2
- ANGPTL2 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs956446911, COSV52221961, COSV99402337; called by muse, mutect2, varscan2
- ANK1 | c.2036G>A p.G679D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.379); catalogued as rs777182935, COSV55881562; called by muse, mutect2, varscan2
- ANK3 | c.2498A>C p.K833T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV55057770; called by muse, mutect2, varscan2
- ANKRD13B | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV61470853; called by muse, mutect2, varscan2
- ANKRD27 | c.3110G>A p.G1037D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1568392131, COSV60131555; called by muse, mutect2, varscan2
- ANKRD34A | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.631); catalogued as COSV60160938; called by muse, mutect2, varscan2
- ANKRD40 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 38/98 reads (39%) | catalogued as rs772776762, COSV53321634; called by muse, mutect2, varscan2
- ANKRD44 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56555064; called by muse, mutect2, varscan2
- ANKRD50 | c.3429_3430insT p.G1144Wfs*12 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as COSV72385548; called by pindel, varscan2
- ANKRD50 | c.997T>A p.L333I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72385550; called by muse, mutect2, varscan2
- ANXA2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as rs774410888, COSV60316814; called by muse, mutect2, varscan2
- ANXA5 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780076315, COSV56638950; called by muse, mutect2, varscan2
- ANXA9 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs112833633, COSV64484797; called by muse, mutect2, varscan2
- AP002512.3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54405433; called by muse, mutect2, varscan2
- AP1G1 | c.204G>A p.L68= | Splice Region (SNP) | VAF 40/97 reads (41%) | catalogued as COSV55489220; called by muse, mutect2, varscan2
- AP2B1 | c.1844T>C p.L615P | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51999478; called by muse, mutect2
- AP3B2 | c.1874G>A p.G625D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1196607606, COSV55609554, COSV99915901; called by muse, mutect2, varscan2
- AP5B1 | c.2507del p.P836Rfs*65 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | catalogued as COSV57505057; called by mutect2, pindel
- APBA1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV55227985; called by muse, mutect2, varscan2
- APEX1 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51657697; called by muse, mutect2, varscan2
- APLP1 | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV52876370, COSV52878522; called by muse, mutect2, varscan2
- APOBEC3H | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0.013); catalogued as rs947813764, COSV62378715; called by muse, mutect2, varscan2
- APOL4 | c.562G>A p.A188T (on ENST00000352371 / NM_145660.2; = p.A185T on NM_030643.4) | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs746034036, COSV60654725; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs3215969; called by pindel, varscan2
- AR | c.336G>T p.E112D | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.138); catalogued as COSV65956996; called by muse, mutect2, varscan2
- ARAF | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51692705; called by muse, mutect2, varscan2
- ARAP2 | c.3367C>T p.L1123F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs780333865, COSV58286685; called by muse, mutect2, varscan2
- ARC | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV63078515; called by muse, mutect2, varscan2
- ARF4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57715072; called by muse, mutect2, varscan2
- ARHGAP19 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as rs1308783043, COSV57391851, COSV57392936; called by muse, mutect2, varscan2
- ARHGAP30 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757669760, COSV63515484; called by muse, mutect2, varscan2
- ARHGAP31 | c.3710G>A p.S1237N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99956393; called by muse, mutect2, varscan2
- ARHGAP32 | c.2104C>T p.R702C (on ENST00000310343 / NM_001378025.1; = p.R353C on NM_014715.4) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs766918157, COSV59847715; called by muse, mutect2, varscan2
- ARHGAP32 | c.1736C>T p.A579V (on ENST00000310343 / NM_001378025.1; = p.A230V on NM_014715.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV59847732; called by muse, mutect2
- ARHGAP5 | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs371418384; called by muse, mutect2, varscan2
- ARHGEF10L | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs140059332, COSV63417329; called by muse, mutect2, varscan2
- ARHGEF12 | c.3010T>C p.Y1004H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.517); catalogued as COSV63104642; called by muse, mutect2, varscan2
- ARHGEF25 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1278195704; called by muse, mutect2
- ARHGEF26 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs776704269, COSV62846440; called by muse, mutect2, varscan2
- ARID1A | c.2332G>A p.G778R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs990194975, COSV100252419, COSV61377609; called by muse, varscan2
- ARID5B | c.2089T>C p.S697P | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54420454; called by muse, mutect2, varscan2
- ARL10 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV59990668; called by muse, mutect2, varscan2
- ARL6IP6 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100423841; called by muse, mutect2, varscan2
- ARMC4 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs776741018, COSV99518015; called by muse, mutect2, varscan2
- ARSD | c.1725del p.C576Afs*31 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as COSV101144909, COSV66973076, COSV66973308; called by mutect2, pindel, varscan2
- ARV1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as rs368169867; called by muse, mutect2, varscan2
- ASAP2 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55631595; called by muse, mutect2, varscan2
- ASAP2 | c.2166C>A p.S722R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55631605; called by muse, mutect2, varscan2
- ASB17 | c.530dup p.N177Kfs*21 | Frame Shift Ins (INS) | VAF 33/93 reads (35%) | catalogued as rs749460467; called by mutect2, varscan2
- ASB3 | c.1114G>T p.G372* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV55075843, COSV99711709; called by muse, mutect2, varscan2
- ASB4 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.292); catalogued as COSV57945249; called by muse, mutect2, varscan2
- ASB5 | c.929T>C p.L310S | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.792); catalogued as COSV56670655; called by muse, mutect2, varscan2
- ASH1L | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs755792596, COSV64207562; called by muse, mutect2, varscan2
- ASL | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.886); catalogued as COSV100508776; called by muse, mutect2, varscan2
- ATG2A | c.3101C>T p.S1034L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs766516929, COSV65966820; called by muse, mutect2, varscan2
- ATG2B | c.887T>A p.L296H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63423123; called by muse, mutect2, varscan2
- ATG4D | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV57264560, COSV57265870; called by muse, varscan2
- ATIC | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52693058; called by muse, mutect2, varscan2
- ATP12A | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754417500, COSV54516072; called by muse, mutect2, varscan2
- ATP13A3 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs781676172, COSV55464557; called by muse, mutect2, varscan2
- ATP1B4 | c.839G>T p.R280L (on ENST00000218008 / NM_001142447.3; = p.R276L on NM_012069.5) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.76); catalogued as COSV54312768, COSV54314743; called by muse, mutect2, varscan2
- ATP2A3 | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs766610781, COSV59229181; called by muse, mutect2, varscan2
- ATP6AP2 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV65797651; called by muse, mutect2, varscan2
- ATP8B3 | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100033784; called by muse, mutect2, varscan2
- ATP8B4 | c.2770A>T p.I924F | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV52715423; called by muse, mutect2, varscan2
- ATRX | c.4273A>G p.R1425G | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV64876499; called by muse, mutect2, varscan2
- ATXN1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 59/68 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371662453; called by muse, mutect2, varscan2
- ATXN2 | c.3007A>G p.M1003V (on ENST00000550104; = p.M843V on NM_002973.4) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.824); catalogued as COSV66483204; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- ATXN7 | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55750731; called by muse, mutect2, varscan2
- ATXN7L1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1032524406, COSV59492996; called by muse, mutect2, varscan2
- AVIL | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV57681827; called by muse, mutect2, varscan2
- AXIN1 | c.64del p.R22Dfs*62 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as COSV51994223; called by mutect2, pindel, varscan2
- B4GALNT2 | c.1363G>T p.G455* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV55926128; called by muse, mutect2, varscan2
- BABAM2 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as rs1445947949, COSV56220125; called by muse, mutect2, varscan2
- BACE1 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57284793; called by muse, mutect2, varscan2
- BAHD1 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as COSV69083968; called by muse, mutect2, varscan2
- BANP | c.1110C>A p.H370Q (on ENST00000286122; = p.H339Q on NM_017869.4) | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.972); catalogued as COSV53737604; called by muse, mutect2, varscan2
- BBS12 | c.1445T>C p.V482A | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV58562076; called by muse, mutect2, varscan2
- BCAT1 | c.540A>C p.K180N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV53911369; called by muse, mutect2, varscan2
- BCCIP | c.881T>G p.V294G | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV52940613, COSV99501245; called by muse, mutect2, varscan2
- BCHE | c.990G>A p.M330I | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs762936157, COSV52256862; called by muse, mutect2, varscan2
- BCL2L14 | c.974_976del p.E325del | In Frame Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs777239665; called by pindel, varscan2
- BCL6B | c.1313A>G p.K438R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV53427810; called by muse, mutect2, varscan2
- BEST1 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as rs1378679988, CM111684, COSV57120821; called by muse, mutect2, varscan2
- BGN | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59036862; called by muse, mutect2, varscan2
- BICDL1 | c.1666del p.D556Mfs*57 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs755289629, COSV99984716; called by mutect2, pindel, varscan2
- BID | c.146G>A p.C49Y (on ENST00000317361 / NM_197966.2; = p.C3Y on NM_001196.4) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV58006822; called by muse, mutect2, varscan2
- BIRC6 | c.9156G>T p.M3052I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs758975775, COSV70194973, COSV70199208; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.019); catalogued as COSV57279575; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4319C>T p.A1440V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.972); catalogued as COSV63245082; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, mutect2, varscan2
- BMPER | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as rs144985513; called by muse, mutect2, varscan2
- BMS1 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs1303300696, COSV65733868; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs763134487; called by mutect2, varscan2
- BRWD3 | c.3793A>G p.T1265A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV64748128; called by muse, mutect2, varscan2
- BST1 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV53946675; called by muse, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs777776928; called by mutect2, varscan2
- BTG4 | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV63635123, COSV63635581; called by muse, mutect2, varscan2
- C10orf67 | c.152G>A p.R51H (on ENST00000323327; = p.R52H on NM_153714.3) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60113505; called by muse, mutect2
- C19orf44 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV99549862; called by muse, mutect2, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | catalogued as rs781818365; called by mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel
- C2orf16 | c.3223G>T p.A1075S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV62675563; called by muse, mutect2, varscan2
- C3orf62 | c.289C>A p.H97N | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.076); catalogued as COSV99648851; called by muse, mutect2, varscan2
- C7orf31 | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV52217314; called by muse, mutect2, varscan2
- CA10 | c.831G>C p.Q277H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.983); catalogued as rs938814454, COSV53349734; called by muse, mutect2, varscan2
- CA3 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs766830102, COSV53409888; called by muse, mutect2, varscan2
- CABIN1 | c.5803C>T p.R1935* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV54081692; called by muse, mutect2, varscan2
- CABIN1 | c.5992C>T p.R1998W | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.425); catalogued as rs763783967, COSV54081258, COSV99573121; called by muse, mutect2, varscan2
- CACFD1 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); catalogued as COSV99390043; called by muse, mutect2, varscan2
- CACNA1A | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV64197945; called by muse, mutect2, varscan2
- CACNA1A | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs576099495, COSV64197963; called by muse, mutect2, varscan2
- CACNA1C | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057518445, COSV100214148, COSV59696139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1G | c.4326G>T p.Q1442H | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV61727189; called by muse, mutect2, varscan2
- CACNA1G | c.5900C>A p.P1967H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV61727215; called by muse, mutect2, varscan2
- CACNA1I | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.932); catalogued as COSV100358843; called by muse, mutect2, varscan2
- CACNG3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV50064715; called by muse, mutect2, varscan2
- CACTIN | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs371323853; called by muse, mutect2, varscan2
- CADPS2 | c.3554del p.N1185Tfs*15 | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | catalogued as rs1159190836; called by mutect2, pindel, varscan2
- CALU | c.600A>G p.I200M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV50821730; called by muse, mutect2, varscan2
- CAMK4 | c.237A>C p.K79N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56670833; called by muse, mutect2, varscan2
- CAMSAP1 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV56722616; called by muse, mutect2, varscan2
- CAMTA1 | c.3062C>T p.A1021V | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV57900663; called by muse, mutect2, varscan2
- CAMTA1 | c.3722C>T p.P1241L | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1219458975, COSV57898622; called by muse, mutect2, varscan2
- CAPN7 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.378); catalogued as rs776786847, COSV53778148, COSV53778796, COSV99512580; called by muse, mutect2, varscan2
- CAPRIN1 | c.1364C>T p.T455I | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV58219808; called by muse, mutect2, varscan2
- CAPS2 | c.1462T>C p.S488P | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60825495; called by muse, mutect2, varscan2
- CARS2 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs367861934; called by muse, mutect2
- CASK | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV59366563; called by muse, mutect2, varscan2
- CASP8 | c.897C>A p.Y299* (on ENST00000432109 / NM_033355.3; = p.Y316* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV51849604; called by muse, mutect2, varscan2
- CATSPERG | c.3018C>T p.I1006= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as rs768355442, COSV53048669; called by muse, mutect2, varscan2
- CBWD2 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99380060; called by mutect2, varscan2
- CCDC113 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs765930226, COSV54686028, COSV54688390; called by muse, mutect2, varscan2
- CCDC12 | c.73C>A p.L25I (on ENST00000425441 / NM_001277074.1; = p.L38I on NM_144716.5) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52757736; called by muse, mutect2, varscan2
- CCDC146 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 130/465 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV53548367; called by muse, mutect2, varscan2
- CCDC157 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs201598906; called by muse, mutect2, varscan2
- CCDC28A | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751125896, COSV60424981; called by muse, mutect2, varscan2
- CCDC65 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as rs759186574, COSV56739560; called by muse, mutect2, varscan2
- CCDC74B | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV60102107; called by muse, mutect2, varscan2
- CCDC87 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100039665, COSV59579941; called by muse, mutect2, varscan2
- CCDC89 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs753113157, COSV57034021; called by muse, mutect2, varscan2
- CCDC96 | c.694T>C p.Y232H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV59508630; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCNL1 | c.1030A>T p.R344* | Nonsense Mutation (SNP) | VAF 56/137 reads (41%) | catalogued as COSV55819296; called by muse, mutect2, varscan2
- CCP110 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142274455; called by muse, mutect2, varscan2
- CCR1 | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV56122198; called by muse, mutect2, varscan2
- CD300A | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60410102; called by muse, mutect2, varscan2
- CDC25B | c.1487G>A p.R496H (on ENST00000245960 / NM_021873.3; = p.R482H on NM_004358.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55656534; called by muse, mutect2, varscan2
- CDC42BPA | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV62010936; called by muse, mutect2, varscan2
- CDC45 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV54245383; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | catalogued as rs762194001; called by mutect2, varscan2
- CDCA2 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs767647125, COSV57945898; called by muse, mutect2, varscan2
- CDCA7L | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.683); catalogued as rs749525504, COSV62259156; called by muse, mutect2, varscan2
- CDH12 | c.1120A>G p.S374G | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV66436512; called by muse, mutect2, varscan2
- CDH22 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64837559; called by muse, mutect2
- CDH23 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs564161575, COSV99818122, COSV99823119; called by muse, mutect2, varscan2
- CDK11B | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100477043; called by muse, mutect2, varscan2
- CDK2 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57186570; called by muse, mutect2, varscan2
- CDKL4 | c.67A>C p.N23H | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.46); catalogued as COSV101115045; called by muse, mutect2, varscan2
- CDKN1A | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs376481017, COSV55188894; called by muse, mutect2, varscan2
- CDS2 | c.724T>G p.F242V | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100986046; called by muse, mutect2, varscan2
- CDYL2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1343799325, COSV73654194; called by muse, mutect2, varscan2
- CELF4 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58453142; called by muse, mutect2, varscan2
- CELSR2 | c.7356C>A p.C2452* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV54771737; called by muse, mutect2, varscan2
- CEMIP | c.2233A>G p.T745A | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99585792; called by muse, mutect2, varscan2
- CEP170 | c.3757A>G p.K1253E | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100316236, COSV60509022; called by muse, mutect2, varscan2
- CEP350 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs142866051, COSV62601008; called by muse, mutect2, varscan2
- CEP85L | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100873951, COSV63822133; called by muse, mutect2, varscan2
- CEP97 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV59124587; called by muse, mutect2, varscan2
- CERS6 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV59830201; called by muse, mutect2
- CES1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376173751, COSV100828511; called by muse, mutect2, varscan2
- CES1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1351062972, COSV62086174; called by muse, mutect2, varscan2
- CFHR1 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV57626584, COSV57627096; called by muse, mutect2, varscan2
- CFTR | c.2647C>T p.L883F | Missense Mutation (SNP) | VAF 80/229 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV50053135; called by muse, mutect2, varscan2
- CGNL1 | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.482); catalogued as rs745940993, COSV55564515; called by muse, mutect2, varscan2
- CHD3 | c.1102del p.E368Rfs*116 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as COSV57873257, COSV57874790; called by mutect2, pindel, varscan2
- CHD6 | c.8059G>A p.E2687K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); catalogued as rs374665904, COSV100950487; called by muse, mutect2, varscan2
- CHD7 | c.6352A>G p.N2118D | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV71110403; called by muse, mutect2
- CHD8 | c.7112dup p.N2371Kfs*2 (on ENST00000646647 / NM_001170629.2; = p.N2092Kfs*2 on NM_020920.4) | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | catalogued as rs751094013; called by mutect2, varscan2
- CHD8 | c.5267A>C p.Y1756S (on ENST00000646647 / NM_001170629.2; = p.Y1477S on NM_020920.4) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as COSV63036818; called by muse, mutect2, varscan2
- CHERP | c.1996T>C p.Y666H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52224434; called by muse, mutect2, varscan2
- CHRNA10 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs758227414, COSV51704506; called by muse, mutect2, varscan2
- CHRNA2 | c.1330T>G p.S444A | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV99531798; called by muse, mutect2, varscan2
- CHSY1 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.16); catalogued as COSV54253285; called by muse, mutect2, varscan2
- CIPC | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs773785918, COSV62376759; called by mutect2, varscan2
- CLASRP | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.17); catalogued as rs1020929443, COSV55516250; called by muse, mutect2, varscan2
- CLCN2 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55601149; called by muse, mutect2, varscan2
- CLCNKA | c.974C>A p.P325H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.99); catalogued as COSV58891587; called by muse, mutect2, varscan2
- CLCNKA | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58891597; called by muse, mutect2, varscan2
- CLEC2D | c.307T>C p.C103R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51995074, COSV99324813; called by muse, mutect2, varscan2
- CLINT1 | c.431G>T p.R144M | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV51624079; called by muse, mutect2
- CLK3 | c.1636A>G p.I546V (on ENST00000395066 / NM_001130028.1; = p.I398V on NM_003992.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV59340205; called by muse, mutect2, varscan2
- CLN8 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV58670458; called by muse, varscan2
- CLUH | c.3893C>T p.P1298L (on ENST00000435359; = p.P1337L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV101425868, COSV70928671; called by muse, mutect2, varscan2
- CMIP | c.1187T>A p.V396D (on ENST00000537098 / NM_198390.2; = p.V302D on NM_030629.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV101220823; called by muse, mutect2
- CMTR2 | c.2088T>A p.N696K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV57603382; called by muse, mutect2, varscan2
- CNDP1 | c.156G>A p.T52= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs769897803, COSV62593928; called by muse, mutect2, varscan2
- CNFN | c.45C>A p.S15R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55771901; called by muse, mutect2, varscan2
- CNGA1 | c.1327del p.T443Qfs*8 | Frame Shift Del (DEL) | VAF 36/98 reads (37%) | catalogued as rs772867912; called by mutect2, varscan2
- CNGB1 | c.3538G>A p.A1180T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs753863333, COSV51900813; called by muse, mutect2, varscan2
- CNN2 | c.894A>C p.E298D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV99564857; called by muse, mutect2, varscan2
- CNP | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66368081; called by muse, mutect2, varscan2
- CNR1 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.383); catalogued as COSV100759128; called by muse, mutect2
- CNR2 | c.1010T>C p.V337A | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100991197; called by muse, mutect2, varscan2
- CNTN3 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs1362315570, COSV55171188; called by muse, mutect2, varscan2
- CNTN3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1418842277, COSV55164966, COSV55169547; called by muse, mutect2, varscan2
- CNTN6 | c.2678del p.P893Qfs*22 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as COSV63173207; called by mutect2, pindel, varscan2
- CNTNAP3 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 91/291 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV52664017, COSV52667704; called by muse, mutect2, varscan2
- CNTNAP4 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs148104897; called by muse, mutect2, varscan2
- COBL | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs370348190; called by muse, mutect2, varscan2
- COBL | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs139848390; called by muse, mutect2, varscan2
- COL11A1 | c.5153C>T p.A1718V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1285281134, COSV62183578; called by muse, mutect2, varscan2
- COL11A1 | c.1636C>G p.P546A | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777447423, COSV62183245; called by mutect2, varscan2
- COL12A1 | c.4739G>A p.S1580N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs761539038, COSV59395966; called by muse, mutect2, varscan2
- COL16A1 | c.4220G>T p.G1407V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54705719; called by muse, mutect2, varscan2
- COL16A1 | c.3062G>A p.G1021D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV54705735; called by muse, mutect2, varscan2
- COL18A1 | c.3634G>A p.G1212R (on ENST00000359759 / NM_130444.3; = p.G977R on NM_030582.4) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780841902, COSV60588812; called by muse, mutect2, varscan2
- COL1A1 | c.3794G>A p.C1265Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as CD961898, COSV56804874; called by muse, mutect2, varscan2
- COL22A1 | c.3151-1G>T p.X1051_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as COSV57336752; called by muse, mutect2, varscan2
- COL4A2 | c.4524G>A p.M1508I | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64628253; called by muse, mutect2, varscan2
- COL5A1 | c.1510C>A p.P504T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV65668905; called by muse, mutect2, varscan2
- COL5A3 | c.3137G>C p.G1046A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1461090238, COSV99317982; called by muse, mutect2
- COL6A1 | c.2986G>A p.V996M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs764765574, COSV62613222; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs905662421, COSV55087815, COSV55109749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.1262G>T p.R421M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV62025181; called by muse, mutect2, varscan2
- COL6A6 | c.5897C>A p.A1966D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV62025196; called by muse, mutect2, varscan2
- COL7A1 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV60395208; called by muse, mutect2, varscan2
- COLGALT2 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as rs779934343, COSV62298819; called by mutect2, varscan2
- COMP | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.411); catalogued as COSV99721247; called by muse, mutect2
- COPB2 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60812558; called by muse, mutect2, varscan2
- COQ9 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV52645811; called by muse, mutect2, varscan2
- CORO2B | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as rs140464148; called by muse, mutect2, varscan2
- COX10 | c.1244G>A p.S415N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55405029; called by muse, varscan2
- COX15 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50012226; called by muse, mutect2, varscan2
- CPA6 | c.254A>G p.H85R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs756306763, COSV52729318; called by muse, mutect2, varscan2
- CPB1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99294020; called by muse, mutect2, varscan2
- CPT1B | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs745866439, COSV100376805, COSV56415475; called by muse, mutect2, varscan2
- CPT1B | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141802871; called by muse, mutect2, varscan2
- CR1 | c.4861C>T p.P1621S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV65458197; called by muse, mutect2, varscan2
- CRKL | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.95); catalogued as rs976691655, COSV62883249; called by muse, mutect2, varscan2
- CROCC | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.044); catalogued as rs762580426, COSV100978004; called by muse, mutect2, varscan2
- CROCC | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761796681, COSV65012021; called by muse, mutect2, varscan2
- CROCC | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs755908527, COSV65012024; called by muse, mutect2, varscan2
- CRTC1 | c.1277del p.P426Qfs*85 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | catalogued as rs760791352; called by mutect2, pindel, varscan2
- CRY1 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs770965692, COSV50482748; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.8915C>A p.S2972Y (on ENST00000297405 / NM_001363185.1; = p.S2803Y on NM_052900.3) | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52179826; called by muse, mutect2, varscan2
- CSMD3 | c.5618C>A p.T1873K (on ENST00000297405 / NM_001363185.1; = p.T1769K on NM_052900.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV52179843; called by muse, mutect2, varscan2
- CSNK1E | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.079); catalogued as rs749796700, COSV63290381; called by muse, mutect2, varscan2
- CSNK1G3 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62054619, COSV62056972; called by muse, mutect2, varscan2
- CSPG4 | c.5609A>G p.Y1870C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100413191; called by muse, mutect2, varscan2
- CSPG5 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.93); catalogued as COSV53131246; called by muse, mutect2, varscan2
- CSTF1 | c.1296A>T p.*432Cext*25 | Nonstop Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV53858749, COSV53859938; called by muse, mutect2, varscan2
- CTDSPL2 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52946115; called by muse, varscan2
- CTNNA2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1335168432, COSV63566983; called by muse, mutect2, varscan2
- CTRB2 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57315660; called by muse, mutect2, varscan2
- CTRC | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV65621471; called by muse, mutect2, varscan2
- CTSO | c.396C>A p.C132* | Nonsense Mutation (SNP) | VAF 23/42 reads (55%) | catalogued as COSV70809129, COSV70809517; called by muse, mutect2, varscan2
- CTTNBP2 | c.2119del p.L707Wfs*54 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as COSV50390826; called by mutect2, pindel, varscan2
- CTTNBP2 | c.997G>T p.G333W | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV50401949; called by muse, mutect2, varscan2
- CUBN | c.4519A>G p.T1507A | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV64715623; called by muse, mutect2, varscan2
- CUL4B | c.388T>C p.F130L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60687770; called by muse, mutect2, varscan2
- CXCL1 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67611620; called by muse, mutect2, varscan2
- CYB561 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.823); catalogued as rs376683537, COSV100669192; called by muse, mutect2, varscan2
- CYFIP1 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as rs948583277; called by muse, mutect2, varscan2
- CYP2F1 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1198261726, COSV58527442; called by muse, mutect2, varscan2
- DACT3 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.401); catalogued as rs1408445263, COSV100340124; called by muse, mutect2, varscan2
- DAGLA | c.96-1G>T p.X32_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | catalogued as COSV57196041; called by muse, mutect2, varscan2
- DARS2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs745810469, COSV53406909; called by muse, mutect2, varscan2
- DCAKD | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100149381; called by muse, mutect2, varscan2
- DCLRE1C | c.2053del p.R685Efs*6 (on ENST00000378278 / NM_001350965.2; = p.R570Efs*6 on NM_022487.4) | Frame Shift Del (DEL) | VAF 34/110 reads (31%) | catalogued as rs915913541; called by mutect2, pindel, varscan2
- DCLRE1C | c.1133C>T p.A378V (on ENST00000378278 / NM_001350965.2; = p.A263V on NM_022487.4) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1295477255, COSV100739668; called by muse, mutect2, varscan2
- DCP1B | c.1622G>T p.R541M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV54968985; called by muse, mutect2, varscan2
- DDIT3 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs377303534, COSV56257971; called by muse, mutect2, varscan2
- DDX21 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs144769035; called by muse, mutect2, varscan2
- DDX3X | c.359G>A p.R120H (on ENST00000399959; = p.R121H on NM_001356.5) | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs1057519446, COSV67863568; called by muse, mutect2, varscan2
- DDX60L | c.1186C>A p.L396M | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52715220; called by muse, mutect2, varscan2
- DENND2C | c.318C>A p.H106Q | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV67921733; called by muse, mutect2, varscan2
- DENND4B | c.1180A>G p.S394G | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63409148; called by muse, mutect2
- DGKK | c.1130G>A p.C377Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101052840; called by muse, mutect2, varscan2
- DGKK | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.878); catalogued as rs781786278, COSV101052841; called by muse, mutect2, varscan2
- DHODH | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889797882, COSV54662323; called by muse, mutect2, varscan2
- DHX34 | c.2530G>A p.V844I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs376387877; called by muse, mutect2, varscan2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs749610132; called by mutect2, varscan2
- DIMT1 | c.761del p.N254Tfs*12 | Frame Shift Del (DEL) | VAF 60/176 reads (34%) | catalogued as rs757109196; called by mutect2, pindel, varscan2
- DLG2 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV54644151; called by muse, mutect2, varscan2
- DLX1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.056); catalogued as rs1478285655, COSV59394373; called by muse, mutect2, varscan2
- DMBT1 | c.5003A>T p.D1668V (on ENST00000338354 / NM_001377530.1; = p.D911V on NM_004406.3) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57543770; called by muse, mutect2, varscan2
- DNAH1 | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1559491280, COSV101324307; called by muse, mutect2, varscan2
- DNAH1 | c.10394A>T p.N3465I | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.125); catalogued as COSV70229018; called by muse, mutect2, varscan2
- DNAH17 | c.10342G>T p.G3448* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV67754295; called by muse, varscan2
- DNAH2 | c.7177G>A p.V2393I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as rs1041181059, COSV66719441; called by muse, mutect2, varscan2
- DNAH7 | c.3592G>A p.A1198T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs1166045711, COSV56764840; called by muse, mutect2, varscan2
- DNAH9 | c.13381G>A p.V4461M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374555272; called by muse, mutect2, varscan2
- DNAI4 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100925196; called by muse, mutect2, varscan2
- DNAJC28 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780024643, COSV58721800; called by muse, mutect2, varscan2
- DNHD1 | c.12755T>C p.V4252A | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs993722744, COSV99599218; called by muse, mutect2, varscan2
- DNM3 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV62457892; called by muse, varscan2
- DNMT1 | c.1591A>G p.I531V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.401); catalogued as COSV100531515; called by muse, mutect2, varscan2
- DOCK2 | c.4116A>C p.E1372D | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV56958556; called by muse, mutect2, varscan2
- DOCK2 | c.5193T>A p.S1731R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as COSV56958565; called by muse, mutect2, varscan2
- DOK7 | c.1138G>C p.A380P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs760412846, CD1212495, COSV100403061; called by muse, mutect2, varscan2
- DPF3 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as rs372100997; called by muse, mutect2, varscan2
- DRC7 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs201048078, COSV61053152; called by muse, mutect2, varscan2
- DRD1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773577315, COSV67104582; called by muse, mutect2, varscan2
- DRP2 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV100871764, COSV65810329; called by muse, mutect2, varscan2
- DSEL | c.2054T>A p.I685N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV59491505; called by muse, mutect2, varscan2
- DST | c.15941C>T p.T5314M (on ENST00000361203 / NM_001374722.1; = p.T2902M on NM_015548.5) | Missense Mutation (SNP) | VAF 153/187 reads (82%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as rs756527130, COSV55014242, COSV55029896; called by muse, mutect2, varscan2
- DSTN | c.308dup p.L103Ffs*12 | Frame Shift Ins (INS) | VAF 30/102 reads (29%) | catalogued as rs750962255; called by mutect2, varscan2
- DTX3L | c.1207T>C p.Y403H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99949791; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs746928635; called by mutect2, varscan2
- DUSP29 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV58300594; called by muse, varscan2
- DYNC1H1 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs774677904, COSV100794151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV62094123, COSV99043803; called by muse, mutect2, varscan2
- DYNC2LI1 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV53183490; called by muse, mutect2, varscan2
- DYRK1A | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV58293881; called by muse, mutect2, varscan2
- DYSF | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs139654844, COSV50327758; called by muse, mutect2, varscan2
- EFCAB5 | c.4486C>T p.P1496S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.477); catalogued as COSV100299919, COSV57929981; called by muse, mutect2, varscan2
- EFHC2 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV69553763; called by muse, mutect2, varscan2
- EHD4 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); catalogued as rs770079590, COSV55004816; called by muse, mutect2, varscan2
- EIF4E3 | c.334C>T p.R112* (on ENST00000425534 / NM_001134651.2; = p.R6* on NM_173359.5) | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as rs149437626; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | catalogued as rs751148694; called by mutect2, varscan2
- ELMO3 | c.1249G>A p.G417S (on ENST00000652269; = p.G364S on NM_024712.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1319077122, COSV62606432; called by muse, mutect2, varscan2
- ELMOD1 | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV56192596; called by muse, mutect2, varscan2
- ELP1 | c.3517G>A p.V1173M | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs771339771, COSV65897752; called by muse, mutect2, varscan2
- EME2 | c.257A>C p.E86A | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs773774708, COSV99167587; called by muse, mutect2, varscan2
- EMILIN1 | c.10del p.R4Afs*12 | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | catalogued as rs1553340313; called by mutect2, pindel, varscan2
- EML1 | c.2344G>A p.G782R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369564518, COSV51745111, COSV51745351; called by muse, mutect2, varscan2
- ENPEP | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs753266874, COSV54451014; called by muse, mutect2, varscan2
- ENTHD1 | c.1321C>A p.L441M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV57320248, COSV57323583; called by muse, mutect2, varscan2
- EOMES | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as rs970631914, COSV55412467; called by muse, mutect2, varscan2
- EOMES | c.995dup p.K333Qfs*11 | Frame Shift Ins (INS) | VAF 13/34 reads (38%) | catalogued as rs1309565164; called by mutect2, pindel, varscan2
- EP400 | c.8785C>T p.Q2929* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV57772173; called by muse, mutect2, varscan2
- EPB41L4A | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs750489592, COSV54863740; called by muse, mutect2, varscan2
- EPB41L4A | c.129C>G p.D43E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV54869487; called by muse, mutect2, varscan2
- EPHA7 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV65169328; called by muse, mutect2, varscan2
- EPM2A | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs796052428, CM004551, COSV62296316; called by muse, mutect2, varscan2
- EPN1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50037558; called by muse, mutect2, varscan2
- EPS15 | c.2326G>A p.G776R | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs760176727, COSV100869373; called by muse, mutect2, varscan2
- EPS8L1 | c.868C>T p.R290C (on ENST00000201647 / NM_133180.3; = p.R163C on NM_017729.3) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52380386; called by muse, mutect2, varscan2
- ERCC2 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs757432268, COSV67263358; called by muse, mutect2, varscan2
- ERF | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.082); catalogued as rs767080643, COSV55895893; called by muse, mutect2, varscan2
- ERICH3 | c.4028T>C p.L1343P | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs763764090, COSV58606639; called by muse, mutect2, varscan2
- ERN2 | c.171_172del p.D59Pfs*8 | Frame Shift Del (DEL) | VAF 40/99 reads (40%) | catalogued as COSV56833690; called by mutect2, pindel, varscan2
- ERO1B | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100523850; called by muse, mutect2
- ESR1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.213); catalogued as rs771540162, COSV52790749; called by muse, mutect2, varscan2
- ESYT3 | c.1495A>G p.T499A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV67440865; called by muse, mutect2, varscan2
- ESYT3 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs775812203, COSV67440873; called by muse, mutect2, varscan2
- EVPL | c.3908G>A p.R1303H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV56913625; called by muse, mutect2
- EXOC3L4 | c.1977G>A p.R659= | Splice Region (SNP) | VAF 30/74 reads (41%) | catalogued as rs1236535903, COSV66295524; called by muse, mutect2, varscan2
- F10 | c.142A>G p.M48V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV65021715; called by muse, mutect2, varscan2
- F8 | c.2258A>G p.N753S | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64273405; called by muse, mutect2, varscan2
- FAM111B | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1362628807, COSV59111885; called by muse, mutect2, varscan2
- FAM13A | c.1886A>G p.Y629C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99982643; called by muse, mutect2, varscan2
- FAM169A | c.413G>A p.C138Y | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100998288, COSV65846491; called by muse, mutect2, varscan2
- FAM186B | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs765816251, COSV57720964; called by muse, mutect2, varscan2
- FAM20A | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs759693849; called by muse, mutect2
- FAM227B | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.985); catalogued as rs142808430; called by muse, mutect2, varscan2
- FAM47B | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV61453903, COSV61453928; called by muse, mutect2, varscan2
- FAM71F1 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.365); catalogued as COSV59373626; called by muse, mutect2, varscan2
- FAM83D | c.620T>C p.M207T | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.161); catalogued as rs1321397848, COSV54157430; called by muse, mutect2, varscan2
- FANCL | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as COSV52074454; called by muse, mutect2, varscan2
- FARSA | c.1417A>T p.N473Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53366562; called by muse, mutect2, varscan2
- FASN | c.7379C>T p.A2460V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as rs751413369, COSV60754712; called by muse, mutect2, varscan2
- FASTKD1 | c.10dup p.T4Nfs*34 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs771228336; called by mutect2, varscan2
- FASTKD3 | c.1571C>A p.P524Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52949507; called by muse, mutect2, varscan2
- FAT2 | c.10383del p.Y3462Tfs*16 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs747011618; called by mutect2, pindel, varscan2
- FAT2 | c.9383T>C p.V3128A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.478); catalogued as rs553647582, COSV99941277; called by muse, mutect2, varscan2
- FBN1 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV57316549; called by muse, varscan2
- FBN2 | c.7659dup p.F2554Vfs*4 | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | catalogued as rs748600284; called by mutect2, varscan2
- FBXO15 | c.1024T>C p.F342L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV54045428; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 50/134 reads (37%) | catalogued as rs768979093, COSV55110370; called by mutect2, varscan2
- FCHSD1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs768524300, COSV71300806; called by muse, mutect2, varscan2
- FCRL2 | c.1325A>T p.N442I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV63833543; called by muse, mutect2, varscan2
- FCRLB | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.987); catalogued as COSV61059758; called by muse, mutect2, varscan2
- FER1L5 | c.3868dup p.Q1290Pfs*29 (on ENST00000623019; = p.Q1263Pfs*29 on NM_001293083.2) | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs758641948; called by mutect2, pindel, varscan2
- FER1L6 | c.3146T>A p.V1049E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67549877; called by muse, varscan2
- FES | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs201771040, COSV51576716; called by muse, mutect2, varscan2
- FEV | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55386546; called by muse, mutect2, varscan2
- FGD1 | c.1771C>T p.L591F | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.401); catalogued as COSV64308695; called by muse, mutect2, varscan2
- FGFRL1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as rs759910460, COSV53257591; called by muse, mutect2, varscan2
- FGL2 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 25/102 reads (25%) | catalogued as COSV50381326; called by muse, mutect2, varscan2
- FHDC1 | c.452G>T p.R151M | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV52599856; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs777980924; called by mutect2, varscan2
- FHOD3 | c.2330C>T p.P777L (on ENST00000359247 / NM_001281739.3; = p.P794L on NM_025135.5) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as rs771338841, COSV57173286; called by muse, mutect2, varscan2
- FLG | c.12137C>T p.S4046L | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs752715330, COSV64241792; called by muse, mutect2, varscan2
- FLNC | c.6565G>T p.E2189* | Nonsense Mutation (SNP) | VAF 37/78 reads (47%) | catalogued as COSV100367464; called by muse, mutect2, varscan2
- FLRT2 | c.1620del p.L542Cfs*5 | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | catalogued as rs35593477, COSV58141126; called by mutect2, pindel, varscan2
- FN1 | c.4654G>A p.D1552N | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs140153061, COSV60547202; called by muse, mutect2, varscan2
- FNDC1 | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as rs1269992043; called by mutect2, varscan2
- FNDC3B | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV61042244; called by muse, mutect2, varscan2
- FOCAD | c.2579G>A p.S860N | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV58099021; called by muse, mutect2, varscan2
- FOXA1 | c.838A>G p.S280G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV51650053; called by muse, mutect2
- FOXC1 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV66515957; called by muse, mutect2, varscan2
- FOXF2 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768831466, COSV52525805; called by muse, varscan2
- FOXG1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV57396748; called by muse, mutect2, varscan2
- FOXG1 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.362); catalogued as rs770118439, COSV57394875, COSV57398768; called by muse, mutect2, varscan2
- FOXI1 | c.44G>A p.S15N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.521); catalogued as COSV60388099; called by muse, varscan2
- FOXI1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1271462280, COSV60388596; called by muse, mutect2, varscan2
- FOXN4 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1481675280, COSV54494066; called by muse, varscan2
- FOXO4 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58575263; called by muse, mutect2, varscan2
- FOXP4 | c.1411A>G p.T471A (on ENST00000307972 / NM_001012426.1; = p.T458A on NM_138457.3) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1479099806, COSV57220018; called by muse, mutect2, varscan2
- FRY | c.8975G>T p.R2992M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as COSV66511198; called by muse, mutect2, varscan2
- FSTL5 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1415716855, COSV60195399; called by muse, mutect2, varscan2
- FTMT | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100360151, COSV58419576; called by muse, mutect2, varscan2
- FTSJ1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1135401942, COSV50025841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FYB1 | c.2043C>A p.D681E (on ENST00000351578 / NM_199335.5; = p.D727E on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV60946336; called by muse, mutect2, varscan2
- FZD2 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs746685961, COSV59528162; called by mutect2, varscan2
- GAA | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771258854, COSV56408518; ClinVar: uncertain significance; called by mutect2, varscan2
- GABRA1 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV50104223, COSV99195703; called by muse, mutect2, varscan2
- GABRB1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.094); catalogued as COSV54981483, COSV99782313; called by muse, mutect2, varscan2
- GALNT1 | c.113del p.K38Rfs*11 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | catalogued as rs1225897793; called by mutect2, pindel, varscan2
- GALNT14 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV61105196; called by muse, mutect2, varscan2
- GANAB | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100647734; called by muse, mutect2, varscan2
- GAP43 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100525189; called by muse, mutect2, varscan2
- GAS2L1 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.841); catalogued as COSV53330468; called by muse, mutect2, varscan2
- GATB | c.591C>A p.S197R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99858590; called by muse, mutect2, varscan2
- GBGT1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs376026740; called by muse, mutect2, varscan2
- GCAT | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs139816860; called by muse, mutect2, varscan2
- GCC1 | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV50000978; called by muse, mutect2, varscan2
- GCDH | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs201509112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDF11 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV57689699; called by muse, mutect2, varscan2
- GDPGP1 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs779183203, COSV100292146, COSV61575790; called by muse, mutect2, varscan2
- GIGYF1 | c.2132A>G p.Q711R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51941779, COSV51944504; called by muse, mutect2, varscan2
- GKAP1 | c.585G>A p.E195= | Splice Region (SNP) | VAF 71/171 reads (42%) | catalogued as COSV64488982; called by muse, varscan2
- GLIS2 | c.1123G>C p.A375P | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs779142808, COSV99267229; called by muse, mutect2, varscan2
- GLUD2 | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60151943; called by muse, mutect2, varscan2
- GMIP | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774984532, COSV52556168, COSV99179452; called by muse, mutect2, varscan2
- GNPDA2 | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.211); catalogued as COSV54946726; called by muse, mutect2, varscan2
- GNPTG | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50190040; called by muse, mutect2, varscan2
- GP6 | c.412T>C p.Y138H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs1280466056, COSV59977434; called by muse, mutect2, varscan2
- GPC5 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs138581416; called by muse, mutect2, varscan2
- GPLD1 | c.2221del p.L741* | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs749977099; called by mutect2, pindel, varscan2
- GPR146 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52466061; called by muse, mutect2, varscan2
- GPR149 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs199967865, COSV67667010; called by muse, mutect2, varscan2
- GPR20 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753512870, COSV66684450; called by muse, mutect2, varscan2
- GPR26 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.617); catalogued as COSV99500698; called by muse, mutect2, varscan2
- GPR61 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs949333514, COSV68177657; called by muse, mutect2, varscan2
- GPR83 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs766270236, COSV54718672; called by muse, varscan2
- GPR83 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1228663221, COSV54718683; called by muse, varscan2
- GPRASP1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as COSV100851110, COSV64355581; called by muse, mutect2, varscan2
- GPS2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs760303804, COSV100222573; called by muse, mutect2, varscan2
- GPT | c.557T>C p.I186T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99477283; called by muse, mutect2, varscan2
- GRAMD1A | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769848875, COSV58767042; called by muse, mutect2, varscan2
- GRIA3 | c.1144A>G p.T382A | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV52059579; called by muse, mutect2, varscan2
- GRIK2 | c.1654G>A p.V552I | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs780955412, COSV59712607; called by muse, mutect2, varscan2
- GRIN2B | c.4421A>G p.Y1474C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV74205917; called by muse, mutect2, varscan2
- GRIN2B | c.1934G>A p.S645N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74205918; called by muse, mutect2, varscan2
- GRK2 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57951825; called by muse, mutect2, varscan2
- GRM1 | c.446del p.P149Qfs*11 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | catalogued as rs1207726214, COSV51123015, COSV99267293; called by mutect2, pindel, varscan2
- GRM1 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as rs768125686, COSV51145810; called by muse, mutect2, varscan2
- GRM3 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64468835; called by muse, mutect2, varscan2
- GRM5 | c.2716A>C p.T906P | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.282); catalogued as COSV59588196; called by muse, mutect2, varscan2
- GSDME | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV61651673; called by muse, mutect2, varscan2
- GSX2 | c.250G>T p.G84W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV58842870; called by muse, mutect2, varscan2
- GTF2H1 | c.644T>C p.M215T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV56378233; called by muse, varscan2
- GTF3C2 | c.1682C>A p.A561D | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.558); catalogued as COSV53126611; called by muse, varscan2
- GUSB | c.1849del p.S617Vfs*23 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | catalogued as rs35302712; called by pindel, varscan2
- GXYLT2 | c.1303A>G p.I435V | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs563351437, COSV67474143; called by muse, mutect2, varscan2
- H1-1 | c.513A>C p.K171N | Missense Mutation (SNP) | VAF 120/308 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs762712997, COSV55119441; called by muse, mutect2, varscan2
- H2AB1 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100371422; called by mutect2, varscan2
- H2AC1 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 25/32 reads (78%) | catalogued as rs371301750; called by muse, mutect2, varscan2
- H2AC4 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs199586241, COSV52518758; called by muse, mutect2, varscan2
- H3C2 | c.113del p.K38Sfs*25 | Frame Shift Del (DEL) | VAF 25/48 reads (52%) | catalogued as rs1561919109; called by mutect2, pindel, varscan2
- HACD1 | c.611A>T p.N204I | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV63516404; called by muse, mutect2, varscan2
- HAPLN2 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54815753; called by muse, mutect2, varscan2
- HDAC5 | c.2594T>C p.L865P | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56818932; called by muse, mutect2, varscan2
- HDAC5 | c.1722G>T p.E574D | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56818943; called by muse, mutect2, varscan2
- HDAC6 | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV61928913; called by muse, mutect2, varscan2
- HDGFL1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57751916; called by muse, mutect2, varscan2
- HDGFL3 | c.147del p.F49Lfs*9 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | catalogued as rs1567170453; called by mutect2, pindel, varscan2
- HEATR5B | c.4946T>C p.L1649P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1284160763, COSV99247884; called by muse, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | catalogued as rs771658394; called by mutect2, varscan2
- HEG1 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371922838, COSV100230544; called by muse, mutect2, varscan2
- HERC1 | c.5634del p.V1879Lfs*26 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs1287865515; called by mutect2, varscan2
- HERC2 | c.5206T>C p.Y1736H | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.735); catalogued as COSV55323553; called by muse, mutect2, varscan2
- HES1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as rs1270230843, COSV51684577; called by muse, mutect2, varscan2
- HFM1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV54027118; called by muse, mutect2, varscan2
- HGFAC | c.568del p.R190Gfs*57 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | catalogued as rs1560192016; called by mutect2, pindel, varscan2
- HIGD1A | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as rs561542879, COSV58414926; called by muse, mutect2, varscan2
- HIP1R | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs752398981, COSV53441583; called by muse, mutect2, varscan2
- HIPK2 | c.2688G>C p.E896D | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV61225630; called by muse, mutect2, varscan2
- HIRA | c.1451T>C p.L484P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as COSV99599734; called by muse, mutect2, varscan2
- HJURP | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs771833145, COSV64978773; called by muse, mutect2, varscan2
- HLA-A | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 60/96 reads (63%) | catalogued as rs281864736, COSV65136959; called by muse, mutect2
- HMCN1 | c.2356A>G p.T786A | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.946); catalogued as COSV99622254; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-3del | Splice Region (DEL) | VAF 14/45 reads (31%) | catalogued as rs759915055; called by pindel, varscan2
- HOGA1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.112); catalogued as rs200236086, COSV65706793; called by muse, mutect2, varscan2
- HRH3 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100420399; called by muse, mutect2, varscan2
- HRNR | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.879); catalogued as rs140632596; called by muse, mutect2, varscan2
- HROB | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV55369624; called by muse, mutect2, varscan2
- HROB | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs372663260, COSV55369630; called by muse, mutect2, varscan2
- HS3ST3A1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769229339, COSV52379015; called by muse, mutect2, varscan2
- HS3ST3B1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100714416, COSV62907308; called by muse, mutect2, varscan2
- HS6ST1 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as COSV52128230; called by muse, varscan2
- HS6ST2 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63711694; called by muse, mutect2, varscan2
- HSD17B10 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1556895052, COSV51448023; called by muse, mutect2, varscan2
- HSPA2 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs201797824, COSV55969662, COSV55971630; called by muse, mutect2, varscan2
- HSPA6 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV59059905, COSV59061059; called by muse, mutect2, varscan2
- HSPH1 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765642778, COSV60711429; called by muse, mutect2, varscan2
- HTR3A | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757883375, COSV100248195; called by muse, mutect2
- HTR3E | c.451A>G p.R151G (on ENST00000415389 / NM_001256613.1; = p.R166G on NM_182589.2) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as COSV100093556; called by muse, mutect2, varscan2
- HUS1B | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV57865049; called by muse, mutect2, varscan2
- HYDIN | c.11165A>C p.K3722T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.172); catalogued as COSV66638994; called by muse, mutect2, varscan2
- ICAM5 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs139899408; called by muse, mutect2, varscan2
- IDE | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.149); catalogued as COSV56423319, COSV99794452; called by muse, mutect2, varscan2
- IFIT2 | c.811A>T p.K271* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs770640915, COSV51078943; called by muse, mutect2, varscan2
- IFT81 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs527626533, COSV54362465; called by muse, mutect2, varscan2
- IGDCC4 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV61536796; called by muse, mutect2, varscan2
- IGF2R | c.2780C>T p.T927M | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs779810760, COSV63627920; called by muse, mutect2, varscan2
- IGSF1 | c.2513C>T p.S838L | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs267606355, COSV63836686; called by muse, mutect2, varscan2
- IGSF3 | c.2668C>T p.R890W (on ENST00000369486 / NM_001007237.3; = p.R910W on NM_001542.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1310584591, COSV59590724; called by muse, mutect2, varscan2
- IKZF1 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV58785728; called by muse, mutect2, varscan2
- IKZF5 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs745563418, COSV64397534; called by muse, mutect2, varscan2
- IL11RA | c.934T>C p.W312R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV99426373; called by muse, mutect2, varscan2
- IL17RA | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772844479, COSV100082772; called by muse, mutect2, varscan2
- IL17RA | c.2435A>G p.E812G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); catalogued as COSV100082773; called by muse, mutect2
- IL17RC | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV55968224; called by muse, mutect2, varscan2
- IL18R1 | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV52122719; called by muse, mutect2, varscan2
- IL1RAPL2 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100781276, COSV61157460; called by muse, varscan2
- IL21R | c.25T>A p.L9M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV61970406; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | catalogued as rs745545309; called by mutect2, pindel, varscan2
- IL4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as rs149950065; called by muse, mutect2, varscan2
- IL4I1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs141664132; called by muse, varscan2
- IL4R | c.2050del p.E684Kfs*3 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as rs1201023196; called by mutect2, pindel, varscan2
- ILF3 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs1187519091, COSV51557519; called by muse, mutect2, varscan2
- INSR | c.2360G>T p.S787I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57162646; called by muse, mutect2, varscan2
- IP6K1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1284825712, COSV100391164; called by muse, mutect2, varscan2
- IP6K2 | c.1087T>C p.S363P | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.616); catalogued as COSV99583565; called by muse, mutect2, varscan2
- IPO9 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as COSV64233694; called by muse, mutect2, varscan2
- IQCE | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs779690833, COSV58078400; called by muse, mutect2, varscan2
- IQSEC1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1161508071, COSV56223856, COSV56229401; called by muse, mutect2, varscan2
- IRX3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1200247563, COSV61668084; called by muse, mutect2, varscan2
- ISCA1 | c.232A>C p.I78L | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV58181577; called by muse, mutect2, varscan2
- ISCA2 | c.18del p.S7Rfs*3 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs950263114; called by mutect2, pindel, varscan2
- ISLR2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100679308; called by muse, mutect2, varscan2
- ITGAX | c.1276del p.R426Afs*20 | Frame Shift Del (DEL) | VAF 11/104 reads (11%) | catalogued as rs1316967675; called by mutect2, pindel, varscan2
- ITGB2 | c.1829G>A p.R610Q (on ENST00000302347; = p.R586Q on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs921337956, COSV56610067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGB2 | c.1618C>T p.Q540* (on ENST00000302347; = p.Q516* on NM_000211.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV56610086; called by muse, mutect2, varscan2
- ITIH1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV56254960, COSV99835078; called by muse, mutect2, varscan2
- ITK | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201513154, COSV70061872; called by muse, mutect2, varscan2
- ITK | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.545); catalogued as rs765859749, COSV101439707, COSV70062317; called by muse, mutect2, varscan2
- ITPKB | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs753690167, COSV55261779; called by muse, mutect2, varscan2
- ITPRID1 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.067); catalogued as COSV60074619; called by muse, mutect2, varscan2
- ITSN1 | c.3905G>A p.R1302H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67156817, COSV67157156; called by muse, mutect2, varscan2
- JAG2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778791847, COSV59308616; called by muse, mutect2, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 39/97 reads (40%) | catalogued as rs763250381; called by mutect2, pindel, varscan2
- JPH1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs1249384156, COSV60608540; called by muse, mutect2, varscan2
- KALRN | c.8353C>T p.R2785* (on ENST00000360013 / NM_001024660.4; = p.R1088* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as rs201835992, COSV99360706; called by muse, varscan2
- KANSL1 | c.2694G>T p.K898N (on ENST00000574590 / NM_001193465.2; = p.K899N on NM_015443.4) | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as COSV52268211; called by muse, mutect2, varscan2
- KAT2A | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs782772503, COSV56790844; called by muse, mutect2, varscan2
- KAT6B | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54746716; called by muse, mutect2, varscan2
- KATNB1 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11555150, COSV65550310; called by muse, mutect2, varscan2
- KAZALD1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs771851844, COSV64630144; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 31/71 reads (44%) | catalogued as rs774820321; called by mutect2, varscan2
- KCNA1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940993, COSV101230079; called by muse, mutect2, varscan2
- KCNB1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.577); catalogued as rs759765009, COSV65568250; called by muse, mutect2, varscan2
- KCNF1 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs764108317, COSV54463453; called by muse, mutect2, varscan2
- KCNH3 | c.3019G>T p.D1007Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as COSV57790781; called by muse, mutect2, varscan2
- KCNH4 | c.642del p.S215Lfs*62 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as COSV99236896; called by mutect2, pindel, varscan2
- KCNH6 | c.2029C>G p.L677V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59003329; called by muse, mutect2, varscan2
- KCNJ1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs764778741, CM014058, COSV100131166; called by muse, mutect2, varscan2
- KCNJ3 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV54536178; called by muse, mutect2, varscan2
- KCNJ8 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53715876; called by muse, mutect2, varscan2
- KCNN3 | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV55216879; called by muse, mutect2
- KCTD1 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1272146130, COSV58683749; called by muse, mutect2, varscan2
- KCTD13 | c.421del p.R141Gfs*13 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs766440565; called by mutect2, pindel, varscan2
- KCTD5 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57064589; called by muse, mutect2, varscan2
- KCTD8 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462314038, COSV63589168; called by muse, mutect2, varscan2
- KDM2A | c.2500del p.R834Vfs*3 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as COSV58189826; called by mutect2, pindel, varscan2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 44/96 reads (46%) | catalogued as rs782541016; called by mutect2, varscan2
- KDM5B | c.1493G>T p.W498L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349855; called by muse, mutect2, varscan2
- KDM6B | c.2226del p.T743Pfs*39 | Frame Shift Del (DEL) | VAF 29/62 reads (47%) | catalogued as COSV54686166; called by mutect2, pindel, varscan2
- KIAA0319L | c.2110A>G p.T704A | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV57845717; called by muse, mutect2, varscan2
- KIAA1109 | c.14701G>A p.D4901N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs368229897, COSV52672872; called by muse, mutect2, varscan2
- KIF15 | c.3230A>G p.E1077G | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV58160837; called by muse, mutect2, varscan2
- KIF26A | c.1329C>T p.A443= | Splice Region (SNP) | VAF 13/31 reads (42%) | catalogued as rs550657002, COSV59466584; called by muse, mutect2, varscan2
- KIF3C | c.1682T>C p.M561T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV53099301; called by muse, mutect2, varscan2
- KIF3C | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53099313; called by muse, mutect2, varscan2
- KIF5C | c.2864A>G p.Y955C | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1055992144, COSV68481246; called by muse, mutect2, varscan2
- KLC2 | c.1604A>C p.D535A | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV57582624; called by muse, mutect2, varscan2
- KLC2 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1261523769, COSV57582632; called by muse, mutect2, varscan2
- KLHDC4 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as rs370744310; called by muse, mutect2, varscan2
- KLHL1 | c.1157A>G p.D386G | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1488984193, COSV64772398; called by muse, mutect2, varscan2
- KLHL1 | c.689T>C p.L230P | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64772401; called by muse, mutect2, varscan2
- KLHL11 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100044116, COSV59862758; called by muse, mutect2, varscan2
- KLHL18 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777261722, COSV51745589; called by muse, mutect2, varscan2
- KLHL20 | c.1346G>A p.R449K | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV52941978; called by muse, mutect2, varscan2
- KLHL21 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as rs140427901; called by muse, mutect2, varscan2
- KLHL26 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as rs1284743885, COSV56317350; called by muse, mutect2, varscan2
- KLHL36 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV50719059; called by muse, mutect2, varscan2
- KLHL42 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs201570618, COSV67146336; called by muse, mutect2, varscan2
- KMO | c.423_425del p.E143del | In Frame Del (DEL) | VAF 18/57 reads (32%) | catalogued as COSV63808613; called by mutect2, pindel, varscan2
- KMT2B | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); catalogued as COSV52890550; called by muse, mutect2, varscan2
- KNDC1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV58835348; called by muse, mutect2, varscan2
- KPNA4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 59/121 reads (49%) | catalogued as COSV62075619; called by muse, mutect2, varscan2
- KPNB1 | c.1378C>A p.L460I | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV51596989; called by muse, mutect2, varscan2
- KPTN | c.273del p.K92Sfs*22 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV99645797; called by mutect2, pindel, varscan2
- KRT20 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99391278; called by muse, mutect2, varscan2
- KRT6C | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771618302, COSV52876377, COSV99359765; called by muse, mutect2
- KRT74 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs748212385, COSV59771429; called by muse, mutect2, varscan2
- KRT9 | c.1191C>A p.S397R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV55853087; called by muse, mutect2, varscan2
- KRTAP15-1 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61877387; called by muse, mutect2, varscan2
- KRTAP20-2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 20/270 reads (7%) | PolyPhen probably damaging (0.958); catalogued as COSV100424408; called by muse, mutect2
- KRTAP9-2 | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs754323661, COSV66646674; called by muse, mutect2, varscan2
- KRTAP9-4 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs369823178; called by muse, varscan2
- KSR1 | c.1252G>A p.A418T (on ENST00000644974 / NM_001367810.1; = p.A281T on NM_014238.2) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.025); catalogued as COSV52032643; called by muse, mutect2, varscan2
- KSR1 | c.1925C>T p.T642M (on ENST00000644974 / NM_001367810.1; = p.T527M on NM_014238.2) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52032655; called by muse, mutect2, varscan2
- L1TD1 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1392018704, COSV63133415; called by muse, mutect2, varscan2
- LAMA1 | c.5672A>G p.N1891S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1568018005, COSV101054462; called by muse, varscan2
- LAMA1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs780440007, COSV67531188; called by muse, mutect2, varscan2
- LAMA2 | c.1649G>A p.G550D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV70347130; called by muse, mutect2, varscan2
- LAMA5 | c.10178C>T p.A3393V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs773233110, COSV53360057; called by muse, mutect2, varscan2
- LAMA5 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as rs760778437, COSV99437296; called by muse, mutect2, varscan2
- LAMB3 | c.2072G>A p.G691D | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs777788000, COSV61915283; called by muse, mutect2, varscan2
- LARP6 | c.1249A>G p.M417V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100150584; called by muse, mutect2, varscan2
- LARP7 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV60520942; called by muse, mutect2, varscan2
- LATS1 | c.179A>G p.E60G | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.115); catalogued as COSV53590721; called by muse, mutect2, varscan2
- LCP2 | c.1157G>A p.S386N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV50450533; called by muse, mutect2, varscan2
- LCT | c.3758C>T p.T1253M | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs772613553, COSV51549287; called by muse, mutect2, varscan2
- LEPR | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV60754716; called by muse, mutect2, varscan2
- LETM1 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs550145512, COSV57101019; called by muse, mutect2, varscan2
- LEXM | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs1334359233, COSV64022655; called by muse, mutect2, varscan2
- LGALS4 | c.605T>G p.L202R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100313037; called by muse, mutect2, varscan2
- LGALS9B | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 73/114 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs768504475, COSV60864961; called by muse, mutect2, varscan2
- LHX6 | c.422G>A p.S141N (on ENST00000373755 / NM_001242334.2; = p.S170N on NM_014368.5) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.208); catalogued as COSV61344699, COSV61346001; called by muse, mutect2, varscan2
- LILRA6 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 134/182 reads (74%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV54435268; called by muse, mutect2, varscan2
- LIPI | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV60711512; called by muse, mutect2, varscan2
- LLGL1 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241448295, COSV57497927; called by muse, mutect2, varscan2
- LMOD1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs763440069, COSV66172684; called by muse, mutect2, varscan2
- LMOD2 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.844); catalogued as COSV101505392, COSV101505417; called by muse, mutect2, varscan2
- LMTK3 | c.2112del p.E705Rfs*153 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs1569103542; called by mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | catalogued as rs748712732; called by mutect2, varscan2
- LNPEP | c.2017T>G p.L673V | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV51477912; called by muse, mutect2, varscan2
- LNX1 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1422431248, COSV55785556; called by muse, mutect2, varscan2
- LPIN3 | c.1139A>G p.D380G | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.358); catalogued as rs1393817187, COSV64718398; called by muse, mutect2, varscan2
- LRCH4 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403834616, COSV53825983; called by muse, mutect2, varscan2
- LRFN4 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as rs1243672632, COSV100540592; called by muse, mutect2, varscan2
- LRP10 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV62078231; called by muse, mutect2
- LRP1B | c.3667A>C p.K1223Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV67219790; called by muse, mutect2, varscan2
- LRP1B | c.1631T>C p.I544T | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs755371701, COSV67219795; called by muse, mutect2, varscan2
- LRRC3 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs764394212, COSV52399252; called by muse, mutect2, varscan2
- LRRC32 | c.1888A>G p.I630V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV52632901; called by muse, mutect2, varscan2
- LRRC37A3 | c.4552G>A p.V1518I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs17842448; called by muse, mutect2, varscan2
- LRRC61 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs149743914, COSV99784710; called by muse, mutect2, varscan2
- LRRC7 | c.46A>G p.R16G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV60544514; called by muse, varscan2
- LRRC71 | c.1373C>A p.P458H | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as COSV59354445; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470del p.K490Nfs*28 | Frame Shift Del (DEL) | VAF 40/87 reads (46%) | catalogued as COSV101280733; called by mutect2, pindel, varscan2
- LRRK2 | c.2129del p.N710Mfs*2 | Frame Shift Del (DEL) | VAF 41/100 reads (41%) | catalogued as COSV54153441; called by mutect2, pindel, varscan2
- LRRK2 | c.4915dup p.R1639Kfs*13 | Frame Shift Ins (INS) | VAF 31/92 reads (34%) | catalogued as rs756089224; called by mutect2, varscan2
- LRRN3 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57819635; called by muse, mutect2, varscan2
- LRRTM4 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.045); catalogued as rs549786608, COSV69162227; called by muse, mutect2, varscan2
- LSM10 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749640330, COSV59872364; called by mutect2, varscan2
- LTF | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as rs776865450, COSV51606041; called by muse, mutect2, varscan2
- LZTS1 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99742505; called by muse, mutect2, varscan2
- MACC1 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV60540669, COSV60542907; called by muse, mutect2, varscan2
- MACF1 | c.3136G>A p.A1046T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs764730015, COSV58373299; called by muse, mutect2, varscan2
- MACF1 | c.21521C>T p.A7174V (on ENST00000372915; = p.A5219V on NM_012090.5) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as COSV57120931; called by muse, mutect2, varscan2
- MACROD1 | c.518-1G>A p.X173_splice | Splice Site (SNP) | VAF 27/65 reads (42%) | catalogued as COSV55360497; called by muse, mutect2, varscan2
- MAEL | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.082); catalogued as rs971792339, COSV100901557; called by muse, varscan2
- MAGEA11 | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.308); catalogued as COSV60755532; called by muse, mutect2, varscan2
- MAGEA11 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.263); catalogued as COSV60755539; called by muse, mutect2, varscan2
- MAGEE1 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV63910214; called by muse, mutect2, varscan2
- MAGEL2 | c.2330C>A p.P777H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV58567173; called by muse, mutect2, varscan2
- MAGI1 | c.3693G>T p.R1231S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58326409; called by muse, mutect2, varscan2
- MAGI2 | c.2569A>G p.T857A | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV62659185; called by muse, mutect2, varscan2
1,726 further variants in this file (1,111 protein-altering or splice-affecting, 563 silent, 52 other) are not listed here.
